Gene-level copy-number profile of tumor specimen TCGA-DQ-7595-01A from TCGA case TCGA-DQ-7595, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3; Age at diagnosis: 53.5 years (19,530 days).
Specimen TCGA-DQ-7595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.9bc3da27-2015-46df-8481-6c34fe996933.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DQ-7595-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5572c806-d839-4847-a7a3-6eab05b2a58c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,001; copy number 2: 46,299; copy number 3: 1,832; copy number 4: 271; copy number 6: 3; copy number 8: 28; copy number 10: 376.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-DQ-7595-01): tumor purity 0.59, ploidy 1.9, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 407 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:47,390–15,330,282, 376 genes, copy number 10 (broad region; genes not listed).
- chr18:21,981,121–22,130,729, 3 genes, copy number 6: LINC01900, AC091043.1, RNU6ATAC20P.
- chr18:26,366,301–28,177,946, 28 genes, copy number 8: RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.

Autosomal genes at a single copy (total copy number 1): 8,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
